Gene-level copy-number profile of tumor specimen TARGET-40-PANMIG-01A from TARGET case TARGET-40-PANMIG, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.7 years (5,360 days).
Specimen TARGET-40-PANMIG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.dfe93ee0-d6d5-5cbf-985b-4d6011357785.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PANMIG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 365 have no estimate.
https://portal.gdc.cancer.gov/files/3a00adc4-d58b-4ab2-93b4-0d77aaeb22af

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 117; copy number 2: 4,469; copy number 3: 11,217; copy number 4: 9,997; copy number 5: 22,327; copy number 6: 8,698; copy number 7: 2,669; copy number 9: 33; copy number 10: 690; copy number 12: 19; copy number 16: 13.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr2:199,269,500–199,471,266, 1 gene (within-gene range 0–3): SATB2.
- chr2:199,457,700–199,750,341, 3 genes: SATB2-AS1, LINC01877, SEPHS1P6.
- chr3:116,921,328–116,932,238, 2 genes: AC069504.1, LINC00901.
- chr11:84,545,131–84,546,846, 1 gene: HNRNPA1P72.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 32 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,403,048–248,919,946, 32 genes, copy number 12–16: OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.

Autosomal genes at a single copy (total copy number 1): 117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
